Surgical pathology report (de-identified scan), TCGA case TCGA-EJ-7791, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site University of Pittsburgh, specimen TCGA-EJ-7791-01A (Primary Tumor).

FINAL DIAGNOSIS:

PART1: LYMPH NODE, RIGHT PELVIC, EXCISION - [REDACTED]
NO EVIDENCE OF NEOPLASIA IN ELEVEN LYMPH NODES (0/11).

PART2: LYMPH NODE, LEFT PELVIC, EXCISION - [REDACTED]
NO EVIDENCE OF NEOPLASIA IN SEVEN LYMPH NODES (0/7).

PART 3: PROSTATE, BILATERAL SEMINAL VESICLES, AND BILATERAL DISTAL VASA DEFERENTIA, RADICAL PROSTATECTOMY -

- A. PROSTATIC ADENOCARCINOMA, ACINAR TYPE, GLEASON SCORE 3 + 4 = 7. GLEASON PATTERN 4 CARCINOMA COMPONENT COMPRISES APPROXIMATELY 10% OF THE EXAMINED TUMOR VOLUME (SLIDES 3GG, 3II).
- B. CARCINOMA INVOLVES BOTH THE RIGHT AND LEFT PROSTATE LOBES AND HAS A GREATEST NODULAR DIAMETER OF 1.5 CM IN A HISTOLOGIC SECTION (SLIDES 3 GG, 3II).
- C. CARCINOMA INVOLVES APPROXIMATELY 15% OF THE EXAMINED PROSTATE VOLUME.
- D. CARCINOMA IS ORGAN CONFINED AND SHOWS NO EVIDENCE OF EXTRACAPSULAR EXTENSION.
- E. FOCAL PERINEURAL INVASION IS IDENTIFIED (SLIDES 3U-3W).
- F. NO ANGIOLYMPHATIC INVASION IS IDENTIFIED.
- G. BILATERAL SEMINAL VESICLES AND DISTAL VASA DEFERENTIA ARE BENIGN.
- H. ALL EXAMINED SURGICAL RESECTION MARGINS ARE FREE OF NEOPLASIA.
- I. MULTIFOCAL HIGH-GRADE PROSTATIC INTRAEPITHELIAL NEOPLASIA IS IDENTIFIED.
- J. PATHOLOGIC TNM STAGE: pT2c N0 MX.
- K. BACKGROUND PROSTATE TISSUE WITH MILD NODULAR HYPERPLASIA, FOCAL CHRONIC INFLAMMATION, AND FOCAL GLANDULAR ATROPHY.

CASE SYNOPSIS:

SYNOPTIC DATA - PRIMARY PROSTATE TUMORS	
CLINICAL DATA:	PSA value: 4.5
INVASIVE CA IDENTIFIED?:	Yes
TUMOR HISTOLOGY:	Adenocarcinoma NOS
PRIMARY GLEASON GRADE:	3
SECONDARY GLEASON GRADE:	4
GLEASON SUM SCORE:	7
GLEASON 4/5 PERCENTAGE:	10%
WEIGHT OF PROSTATE:	47.37gm
TUMOR SIZE:	Maximum dimension: 1.5 cm
LOBE LATERALITY:	Right and Left Lobes
PERCENT OF SPECIMEN INVOLVED BY TUMOR:	5 - 25%
MULTIFOCAL DISEASE:	Yes
HIGH GRADE PIN:	Yes - multifocal
EXTRAPROSTATIC EXTENSION:	No
PERINEURAL INVASION:	Yes
ANGIOLYMPHATIC INVASION:	No
SEMINAL VESICLE INVASION:	No
SURGICAL MARGIN INVOLVEMENT:	All surgical margins free of tumor
RESIDUAL TUMOR:	R0
LYMPH NODES EXAMINED:	18
LYMPH NODES POSITIVE:	0
T STAGE, PATHOLOGIC:	pT2c
N STAGE, PATHOLOGIC:	pN0
M STAGE, PATHOLOGIC:	pMX
HISTOLOGIC GRADE:	G3-4, Poorly differentiated/undifferentiated

PATIENT HISTORY:

The patient is a [REDACTED] year-old [REDACTED] with a serum PSA value of 4.5 ng/mL. He had a prostate needle biopsy on [REDACTED] this biopsy revealed: prostatic adenocarcinoma in the right mid, right apex, and left apex of prostate, Gleason score 3 + 3 = 6. The patient also has a history of rectal prolapse surgery, inguinal hernia repair, and tonsillectomy.

PRE-OP DIAGNOSIS: Prostate cancer.

POST-OP DIAGNOSIS: Same.

PROCEDURE: Radical prostatectomy and bilateral pelvic lymphadenectomy.

Source: NCI Genomic Data Commons file 1125e1df-d82c-4a11-b76f-5bc14a0ac344 (TCGA-EJ-7791.001C43CB-3E9B-43DB-B6D0-61E67D058C9F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).